Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4022, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4022-01A (Primary Tumor).

Diagnosis:

This is an invasive, moderately differentiated, rectal carcinoma (adenocarcinoma of the colon - G2) with penetration of all parietal layers (pT3, L1, V1)

Source: NCI Genomic Data Commons file df4fb622-38f7-48ab-bb68-93d6be53a0a9 (TCGA-AG-4022.919FEE59-C2BA-4563-8B49-BCA8D0E1643B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).